Gene-level copy-number profile of tumor specimen TCGA-CC-A7IL-01A from TCGA case TCGA-CC-A7IL, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 61.1 years (22,319 days).
Specimen TCGA-CC-A7IL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.c60ec134-2bd1-4025-a0fb-0310c87a431f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-A7IL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d5ee87bd-45c8-4c2e-9c6d-ccc52d86571b

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4,506; copy number 2: 16,475; copy number 3: 25,627; copy number 4: 5,563; copy number 5: 5,878; copy number 6: 1,607; copy number 7: 162.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-A7IL-01A-11D-A33P-01): tumor purity 0.93, ploidy 2.89, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 162 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:8,158,162–8,760,447, 1 gene, copy number 7 (within-gene range 6–7): AL355499.2.
- chr6:8,411,435–10,211,608, 5 genes, copy number 7 (within-gene range 6–7): SLC35B3, HULC, AL161437.1, AL137220.1, OFCC1.
- chr6:44,809,317–51,623,428, 87 genes, copy number 7 (broad region; genes not listed).
- chr6:53,739,266–62,286,225, 69 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,126. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
